Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A6J1, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A6J1-01A (Primary Tumor).

[page 1 of 2]
Gender: F

DOB: [REDACTED]

Age: [REDACTED]

Phone: [REDACTED]

Address: [REDACTED]

Result Detail

Pathology Result: [REDACTED]

Specimen Collected Date: [REDACTED]

Specimen Received Date: [REDACTED]

Order Number: [REDACTED]

Ordering Provider: [REDACTED]

Medical Record Number: [REDACTED]

Facility: [REDACTED]

Status: [REDACTED]

Accession #: [REDACTED]

Pathologist: [REDACTED]

Date of Procedure: [REDACTED]

Date Received: [REDACTED]

Date Reported: [REDACTED]

Submitting Physician: [REDACTED]

Location: [REDACTED]

FINAL DIAGNOSIS

A. "TUMOR MARGINS", BIOPSY:

-BLOOD CONTAINING FRAGMENTS OF CEREBRAL CORTEX DEMONSTRATE FOCAL GLIOMATOUS INFILTRATION.

B. "LEFT INTRACRANIAL TUMOR", REMOVAL:

-OLIGODENDROGLIOMA (WHO GRADE II).

Out By [REDACTED]

Electronically Signed

Intraoperative Consultation:

Microscopic diagnosis:

FSAL: Blood cautery with low grade glioma.

Dr. [REDACTED]

ICD-O-3

Oligodendroglioma, grade II 9450/3

Clinical History:

left intracranial tumor

Site: @ Brain, supratentorial NAS C71.0
9/10/13

Specimens Submitted As:

A: TUMOR MARGINS

B: LEFT INTRACRANIAL TISSUE

Gross Description:

A: Received fresh for intraoperative consultation, labeled with the patient's name, hospital number and "margins", is a segment of tan and red soft tissue

measuring 3.0 x 1.5 x 1.2 cm. The specimen is bisected and representative portion is submitted for frozen evaluation and then in one cassette. The remainder is entirely submitted for permanent evaluation in one additional cassette.

B: Received fresh, labeled with the patient's name and number, are multiple light tan to pink-tan irregular soft tissue fragments measuring 2.8 x 2.0 x 0.6

[page 2 of 2]
cm in aggregate. Submitted in toto in one cassette.

■

■

Source: NCI Genomic Data Commons file c7d2cfeb-845a-45dd-a633-f15b7d22a6af (TCGA-FG-A6J1.9421C492-5E69-4641-B4CD-29A4D2C7A4CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).